CCDI case PBCMPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/ec1797e7-b7ac-4b00-a8bb-63796b00a41f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, NOS: ICD-O-3 morphology code: 8590/1; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 2.6 years (945 days).

Biospecimens (3 samples)
- Sample 0DWD1J: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DWD1Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWD28: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
